Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABKE, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABKE-TTP1-A (Primary Tumor).

HISTOPATHOLOGY EXAM

SPECIMEN RECEIVED:

- A) Lymph node, aortic arch, biopsy
- B) Apex of left lung, biopsy

CDDP-YP-ABKE-01-PR

GROSS DESCRIPTION:

- A) Lymph node measuring 1.1 cm. along the major axis
- B) Apex of left lung, measuring 6.7x5.5x3.3 cm. and weighing 52 g., closed with metal suture clips and marked with a tracing suture on the parenchymal margin. The visceral pleura is focally irregular and presents, at the cutting surface, a grayish-white, soft elastic, subpleural neoformation measuring 2.9x2.8x1.8 cm., located 2.4 cm. from the surgical resection margin.
(B1-B3 neoformation-pleura; B4 neoformation-parenchyma; B5 pulmonary parenchyma corresponding to the tracing point.

HISTOPATHOLOGICAL DIAGNOSIS:

- A) Lymph node free of metastasis.
- B) Mixed adenocarcinoma of the lung (acinar and mucinous bronchioalveolar), moderately differentiated (G2), infiltrating the parenchyma. Focal bronchial ectasia in the remaining parenchyma. Resection margin free of neoplasia.

Histopathological assessment of stage: pTNM, pT1, Nx

SNOMED codes:

T-C4480 M-09410
T28600 M-81403

1CD-0-3

adenocarcinoma, with mixed subtypes 8255/3
Site: (L) lung, Nos C34.9

1CD-10

C34.92

hw
2/10/16

Source: NCI Genomic Data Commons file c30d3287-6fac-495e-93c8-4d8b60c70898 (CDDP-ABKE-TTP1.83E10CEF-3304-4759-B5B3-375D7402D85F.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).